Somatic mutation profile of tumor specimen TCGA-EM-A2P2-01A (aliquot TCGA-EM-A2P2-01A-11D-A202-08) from TCGA case TCGA-EM-A2P2, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 46.3 years (16,895 days).
Specimen TCGA-EM-A2P2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9a126688-3e2e-4c89-bca1-f87457eb03e1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A2P2-10A (Blood Derived Normal), aliquot TCGA-EM-A2P2-10A-01D-A202-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b533db2f-acf6-41a3-81a0-54dd8f49c481

The open-access MAF lists 18 somatic variants for this specimen: 16 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 13, Silent 2, Splice Region 1, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALG3 | c.286G>A p.G96R | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs367679074, CM1511085; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CCNT1 | c.1745G>T p.G582V | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.015); catalogued as COSV56064139; called by muse, mutect2, varscan2
- CEP152 | c.2569A>G p.I857V | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV57859025; called by muse, mutect2, varscan2
- CLRN3 | c.520A>T p.T174S | Missense Mutation (SNP) | VAF 67/171 reads (39%) | SIFT tolerated (0.4); PolyPhen benign (0.02); catalogued as COSV100899756; called by muse, mutect2, varscan2
- COL9A2 | c.1903G>A p.G635S | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs768840439, COSV65622703; called by muse, mutect2, varscan2
- FGD4 | c.2054C>T p.A685V | Missense Mutation (SNP) | VAF 62/184 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV56783243; called by muse, mutect2, varscan2
- KIAA1549 | c.2902G>A p.E968K | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.541); catalogued as COSV54312803; called by muse, mutect2, varscan2
- KMT2B | c.4528G>A p.A1510T | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as rs748191051, COSV55860447; called by muse, mutect2, varscan2
- LNX1 | c.132C>G p.C44W | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55785083; called by muse, mutect2, varscan2
- MPDZ | c.4052T>C p.I1351T | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1398772394, COSV59917441; called by muse, mutect2, varscan2
- SPON2 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.61); catalogued as rs779956803, COSV52054763; called by muse, mutect2, varscan2
- TBCK | c.264G>A p.V88= | Splice Region (SNP) | VAF 48/129 reads (37%) | catalogued as COSV56754988; called by muse, mutect2, varscan2
- THEMIS | c.742C>A p.L248I | Missense Mutation (SNP) | VAF 43/93 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64070899, COSV64071188; called by muse, mutect2, varscan2
- WDR59 | c.2647T>G p.L883V | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV50935171; called by muse, mutect2, varscan2
- BRAF | c.1582_1596del p.T528_P532del (on ENST00000288602 / NM_001374244.1; = p.T488_P492del on NM_004333.6 and 3 other RefSeq transcripts) | In Frame Del (DEL) | VAF 16/60 reads (27%) | called by mutect2, pindel
- COL4A2 | c.4669del p.Y1557Mfs*19 | Frame Shift Del (DEL) | VAF 47/158 reads (30%) | called by mutect2, pindel, varscan2
- CLRN3 | c.519G>T p.T173= | Silent (SNP) | VAF 66/169 reads (39%) | catalogued as rs550245323, COSV100899758, COSV64098188; called by muse, mutect2, varscan2
- SPATA31A1 | c.972C>T p.G324= | Silent (SNP) | VAF 236/587 reads (40%) | catalogued as rs1188257033; called by muse, mutect2, varscan2
